Somatic mutation profile of tumor specimen 0DFA9A from CCDI case PBBNSZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 10.4 years (3,802 days).
Specimen 0DFA9A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ebaf8f4-f98e-4399-ba88-ed4630ae88a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFA91 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f0519d5-e12d-440a-a264-34781307cd32

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, 3'UTR 1, Missense Mutation 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRD | c.3506T>A p.L1169Q | Missense Mutation (SNP) | VAF 21/506 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- DRD5 | c.486C>T p.G162= | Silent (SNP) | VAF 24/392 reads (6%) | called by muse, mutect2
- ADGRG6 | c.*216T>A | 3'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- RHBDF2 | c.2152-61C>T | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as rs1209704692; called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/178 reads (15%) | called by muse, varscan2
